Somatic mutation profile of tumor specimen TCGA-EY-A1G7-01A (aliquot TCGA-EY-A1G7-01A-11D-A13L-09) from TCGA case TCGA-EY-A1G7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 86.5 years (31,603 days).
Specimen TCGA-EY-A1G7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77539c0a-7547-47ca-af3f-27bef3bbc3b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1G7-10A (Blood Derived Normal), aliquot TCGA-EY-A1G7-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/478e5939-b0b6-45e7-b5ca-b9c26712237b

The open-access MAF lists 90 somatic variants for this specimen: 74 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, Frame Shift Del 7, Frame Shift Ins 6, Nonsense Mutation 5, In Frame Del 3, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>C p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 101/107 reads (94%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2, varscan2
- ABCC12 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs199509150; called by muse, mutect2, varscan2
- ABI2 | c.1185G>T p.Q395H (on ENST00000295851 / NM_001375719.1; = p.Q328H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53696633, COSV99651623; called by muse, mutect2, varscan2
- ACVR1B | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV57775510; called by muse, mutect2, varscan2
- ACVR1B | c.1138T>A p.Y380N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231244; called by muse, mutect2, varscan2
- ACVR1B | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231246; called by muse, mutect2, varscan2
- ALDH9A1 | c.1103A>C p.K368T | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100699268; called by muse, mutect2, varscan2
- AMZ2 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100703084; called by muse, mutect2, varscan2
- ARID4B | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs559532726, COSV99934931; called by muse, mutect2
- ASAP1 | c.1759G>T p.V587L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs773666790, COSV100726787; called by muse, mutect2, varscan2
- ASH2L | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV99166917; called by muse, mutect2, varscan2
- ATP6V1A | c.716+1G>A p.X239_splice | Splice Site (SNP) | VAF 39/89 reads (44%) | catalogued as rs755278709, COSV99849837; called by muse, mutect2, varscan2
- ATP6V1C1 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs768637648, COSV67777966; called by muse, mutect2, varscan2
- ATP8B4 | c.2938G>A p.V980M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1407207645, COSV99463490; called by muse, mutect2, varscan2
- BAP1 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV99963344; called by muse, mutect2, varscan2
- C1orf112 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199972566; called by muse, mutect2, varscan2
- CACNA2D1 | c.1852A>C p.S618R (on ENST00000356253 / NM_001366867.1; = p.S599R on NM_000722.4) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV100665714; called by muse, mutect2, varscan2
- CADM2 | c.571C>T p.R191* (on ENST00000407528 / NM_001167674.2; = p.R193* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs1299583755, COSV67359184; called by muse, mutect2, varscan2
- DGAT1 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100183905; called by muse, mutect2, varscan2
- DIAPH3 | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99932725; called by muse, mutect2, varscan2
- EEF2 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100500559; called by muse, mutect2, varscan2
- ELAVL1 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 35/82 reads (43%) | catalogued as COSV60966012; called by muse, mutect2, varscan2
- FLG | c.8407G>A p.E2803K | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.082); catalogued as rs370605039; called by muse, mutect2, varscan2
- FMN2 | c.621G>T p.Q207H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV100142444; called by muse, mutect2, varscan2
- GP5 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.328); catalogued as COSV99756165; called by muse, mutect2, varscan2
- IHH | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs371913717, COSV99838583; called by muse, mutect2, varscan2
- KATNIP | c.1321G>C p.V441L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as rs760957442, COSV55175368, COSV55184532, COSV99849736; called by muse, mutect2, varscan2
- LEMD3 | c.1925T>C p.V642A | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100384171; called by muse, mutect2, varscan2
- LPIN3 | c.2345C>T p.S782L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV100182335; called by muse, mutect2, varscan2
- MLLT1 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV53129959, COSV53130123; called by muse, mutect2
- MOV10L1 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1252739218, COSV53171330; called by muse, mutect2, varscan2
- MUC5B | c.9989C>A p.P3330H | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101500012; called by muse, mutect2, varscan2
- MYO16 | c.4109G>A p.R1370Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62761082; called by muse, mutect2
- NLRP3 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs201877163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRX1 | c.1514A>C p.Y505S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99423664; called by muse, mutect2, varscan2
- OR2A25 | c.530dup p.C178Lfs*2 | Frame Shift Ins (INS) | VAF 31/128 reads (24%) | catalogued as rs763117243; called by mutect2, pindel, varscan2
- OR2T3 | c.928A>C p.M310L | Missense Mutation (SNP) | VAF 41/414 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100613049; called by muse, mutect2, varscan2
- PAN3 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99144516; called by muse, mutect2, varscan2
- PDLIM3 | c.242G>A p.R81H (on ENST00000284770 / NM_001257963.1; = p.R248H on NM_014476.6) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs377158204, COSV99507369; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEPD | c.1125C>G p.D375E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV99727252; called by muse, mutect2, varscan2
- PLK3 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1440502350, COSV100943668, COSV64728991; called by muse, mutect2, varscan2
- POLQ | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV99951548; called by muse, mutect2, varscan2
- PRKDC | c.11549A>T p.H3850L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100038268; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- RASL10B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs782263531; called by muse, mutect2, varscan2
- RBM45 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as rs1337825501, COSV53720632; called by muse, mutect2, varscan2
- SEC14L5 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228563; called by muse, mutect2, varscan2
- SEPTIN12 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371195126, CM122364, COSV51616434; ClinVar: risk factor; called by muse, mutect2, varscan2
- SFSWAP | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99905751; called by muse, mutect2, varscan2
- SMPD4 | c.2329C>T p.R777C (on ENST00000409031 / NM_017951.4; = p.R748C on NM_017751.4) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs1380399569, COSV100302120, COSV60082262; called by muse, mutect2, varscan2
- SMPD4 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs1467167954, COSV100302122; called by muse, mutect2, varscan2
- STPG1 | c.841C>T p.R281C (on ENST00000337248 / NM_001199013.2; = p.R234C on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as rs376956450; called by muse, mutect2, varscan2
- TCTE1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs766521922, COSV65255660; called by muse, mutect2, varscan2
- UNKL | c.2063G>A p.R688H (on ENST00000389221 / NM_001372107.1; = p.R638H on NM_001193388.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs146280068; called by muse, varscan2
- ZFHX4 | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51489927; called by muse, mutect2
- ADAMTSL4 | c.2568_2580del p.C858Sfs*86 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- CARMIL3 | c.1841del p.F614Sfs*21 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel*, varscan2
- CDC42BPB | c.1743_1745del p.N581_E582delinsK | In Frame Del (DEL) | VAF 14/51 reads (27%) | called by pindel, varscan2
- CERT1 | c.546_552del p.Y183Lfs*34 (on ENST00000405807 / NM_001130105.1; = p.Y55Lfs*34 on NM_005713.3) | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- CPXM2 | c.1655_1657del p.A552_Y553delinsD | In Frame Del (DEL) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- FBXW7 | c.2001dup p.S668Efs*26 (on ENST00000281708 / NM_001349798.2; = p.S588Efs*26 on NM_018315.5) | Frame Shift Ins (INS) | VAF 29/70 reads (41%) | called by mutect2, pindel, varscan2
- FSIP1 | c.328_329del p.E110Ifs*16 | Frame Shift Del (DEL) | VAF 42/121 reads (35%) | called by mutect2, pindel, varscan2
- JAK2 | c.1928_1930del p.N643_C644delinsS | In Frame Del (DEL) | VAF 29/62 reads (47%) | called by mutect2, pindel, varscan2
- PFAS | c.2031G>T p.K677N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRAMEF17 | c.1339_1352del p.P447Ffs*15 | Frame Shift Del (DEL) | VAF 82/214 reads (38%) | called by mutect2, pindel, varscan2
- RNF43 | c.239dup p.L82Ifs*14 | Frame Shift Ins (INS) | VAF 35/50 reads (70%) | called by mutect2, pindel, varscan2
- SLC2A6 | c.783_789dup p.W264Sfs*5 | Frame Shift Ins (INS) | VAF 34/82 reads (41%) | called by mutect2, varscan2
- TOR2A | c.808_811del p.H270Afs*82 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- ZMAT3 | c.21del p.V8Cfs*72 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- ZNF460 | c.705_706insCCAACCGC p.R236Pfs*231 | Frame Shift Ins (INS) | VAF 16/38 reads (42%) | called by mutect2, varscan2
- ZNF710 | c.1387_1396dup p.T466Ifs*5 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- AKAP9 | c.9681A>G p.V3227= (on ENST00000359028; = p.V3203= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100661872; called by muse, mutect2, varscan2
- ANGPTL2 | c.1125C>T p.R375= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV99400744; called by muse, mutect2, varscan2
- CDH23 | c.8598C>T p.I2866= | Silent (SNP) | VAF 47/146 reads (32%) | catalogued as COSV99818695; called by muse, mutect2, varscan2
- COL5A2 | c.2019C>T p.P673= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100879990; called by muse, mutect2, varscan2
- DHX40 | c.1938T>C p.R646= | Silent (SNP) | VAF 84/89 reads (94%) | catalogued as COSV99232698; called by muse, mutect2, varscan2
- GPR12 | c.459G>A p.T153= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV101197936; called by muse, mutect2, varscan2
- MAN2A1 | c.1038C>T p.C346= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99810394; called by muse, mutect2, varscan2
- MYH1 | c.1467A>G p.Q489= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as rs1036487156, COSV99874825; called by muse, mutect2, varscan2
- P4HA2 | c.828C>T p.I276= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV99386752; called by muse, mutect2, varscan2
- PCDHB3 | c.1638G>A p.L546= | Silent (SNP) | VAF 68/168 reads (40%) | catalogued as COSV99164144; called by muse, mutect2, varscan2
- SLC4A3 | c.1134C>T p.I378= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as rs768613077, COSV99812375; called by muse, mutect2, varscan2
- STAT3 | c.63C>G p.L21= | Silent (SNP) | VAF 25/34 reads (74%) | catalogued as rs541045758, COSV99232380; called by muse, mutect2, varscan2
- TTN | c.74280C>T p.D24760= (on ENST00000591111; = p.D17336= on NM_003319.4) | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs1022970267, COSV100593186; called by muse, mutect2, varscan2
- ZDBF2 | c.244T>C p.L82= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV100984326; called by muse, mutect2, varscan2
- PHACTR4 | c.17-20680C>T | Intron (SNP) | VAF 22/39 reads (56%) | catalogued as COSV100868397, COSV100868471; called by muse, mutect2, varscan2
- SSPOP | n.6699C>T | RNA (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100022115; called by muse, mutect2, varscan2
